Somatic mutation profile of tumor specimen TCGA-73-4658-01A (aliquot TCGA-73-4658-01A-01D-1753-08) from TCGA case TCGA-73-4658, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 80.8 years (29,508 days).
Specimen TCGA-73-4658-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df1cc429-8eca-449c-83c4-8f0d69613bd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-4658-11A (Solid Tissue Normal), aliquot TCGA-73-4658-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be733141-d5f0-4e24-b512-2eaa9786d6ee

The open-access MAF lists 338 somatic variants for this specimen: 263 protein-altering or splice-affecting, 68 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 68, Nonsense Mutation 29, Splice Site 7, Splice Region 3, Intron 3, RNA 3, Frame Shift Del 2, In Frame Del 2, Translation Start Site 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.313_318del p.P105_A106del | In Frame Del (DEL) | VAF 6/54 reads (11%) | hotspot (GDC flag); called by mutect2, pindel
- PTEN | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786204931, CM020755, COSV64290794, COSV64294365; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCC11 | c.3604G>A p.D1202N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100751070; called by muse, mutect2, varscan2
- ABHD10 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99845143; called by muse, mutect2, varscan2
- ACAN | c.6478G>C p.E2160Q | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100719051; called by muse, mutect2
- ACE2 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV99383055; called by muse, mutect2
- ACMSD | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99299413; called by muse, mutect2
- ADAD1 | c.1028A>C p.N343T | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.242); catalogued as COSV99636131; called by muse, mutect2
- ADAMTS5 | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99538209; called by muse, mutect2, varscan2
- ADCY1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs80190930, COSV52035709; called by muse, mutect2
- ADCY8 | c.1012A>T p.I338F | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV99653826; called by muse, mutect2
- ADGRF5 | c.3091C>G p.L1031V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV99346256; called by muse, mutect2
- ADGRL2 | c.3683G>T p.G1228V (on ENST00000370717 / NM_001366005.1; = p.G1172V on NM_012302.4) | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99591037; called by muse, mutect2, varscan2
- ADRA1B | c.97A>T p.S33C | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.378); catalogued as COSV100140390; called by muse, mutect2
- ANKRD7 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99501318; called by muse, mutect2
- APBB2 | c.1753G>A p.E585K (on ENST00000295974 / NM_001166050.2; = p.E586K on NM_004307.2) | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99923910; called by muse, mutect2
- ARAP2 | c.5093A>T p.Q1698L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV100395148, COSV58282943; called by muse, varscan2
- ARHGAP9 | c.1740C>A p.S580R (on ENST00000393797 / NM_001319850.2; = p.S561R on NM_032496.4) | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57363306, COSV99954555; called by muse, mutect2, varscan2
- ARHGEF40 | c.3439G>T p.G1147C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV100070636; called by mutect2, varscan2
- ARID2 | c.1442T>A p.I481N | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV100536839, COSV57600047; called by muse, mutect2
- ASH1L | c.7645G>A p.E2549K (on ENST00000368346 / NM_001366177.2; = p.E2544K on NM_018489.3) | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV100853570; called by muse, mutect2, varscan2
- ATP7B | c.1764G>T p.R588S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV99666884; called by muse, mutect2, varscan2
- ATP8B4 | c.943G>T p.G315* | Nonsense Mutation (SNP) | VAF 26/155 reads (17%) | catalogued as COSV99467052; called by muse, mutect2, varscan2
- BCL11A | c.1838C>A p.A613D (on ENST00000335712 / NM_001365609.1; = p.A647D on NM_018014.4) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV100186331; called by muse, mutect2
- BTN2A1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV100438758; called by muse, mutect2, varscan2
- BUD13 | c.398A>T p.H133L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99496679; called by muse, mutect2, varscan2
- C1GALT1C1 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100485642; called by muse, mutect2
- C6orf15 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as rs747261624, COSV99457145; called by muse, mutect2
- CA3 | c.403A>G p.K135E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.06); catalogued as COSV99570835; called by muse, mutect2, varscan2
- CACNA1B | c.4668G>T p.A1556= | Splice Region (SNP) | VAF 11/86 reads (13%) | catalogued as COSV53112566, COSV99499241; called by muse, mutect2, varscan2
- CAMK2B | c.1973C>A p.S658* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV51658986, COSV99323408; called by muse, mutect2
- CBLB | c.1034G>C p.C345S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV99914124; called by muse, mutect2, varscan2
- CCDC3 | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as COSV101121744; called by muse, mutect2
- CCSER2 | c.634T>C p.S212P | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV99826363; called by muse, mutect2, varscan2
- CD14 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs750343901, COSV100117628; called by muse, mutect2, varscan2
- CDH10 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100052751; called by muse, mutect2, varscan2
- CDK10 | c.437A>C p.Q146P (on ENST00000353379 / NM_052988.5; = p.Q75P on NM_052987.4) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99232476; called by muse, mutect2, varscan2
- CEP128 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 11/170 reads (6%) | catalogued as COSV99383608; called by muse, mutect2
- CFAP52 | c.723T>A p.D241E | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100235510; called by muse, mutect2
- CLDN18 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.983); catalogued as rs369029508, COSV59304518; called by muse, mutect2, varscan2
- CLVS1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV100370526; called by muse, mutect2, varscan2
- CMTR2 | c.346T>C p.C116R | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100579318; called by muse, mutect2, varscan2
- CNN3 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 4/63 reads (6%) | catalogued as COSV100930956; called by muse, mutect2
- CNOT1 | c.5818G>T p.V1940F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99801020; called by muse, mutect2, varscan2
- CNOT4 | c.1013C>G p.S338* (on ENST00000315544 / NM_001190848.1; = p.S335* on NM_013316.4) | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100212104; called by muse, mutect2, varscan2
- CNST | c.1859T>C p.V620A | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100830305; called by muse, mutect2
- CNTNAP4 | c.1843G>T p.G615C | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100272878; called by muse, mutect2, varscan2
- COL16A1 | c.3710G>A p.G1237E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595259; called by muse, mutect2
- COL24A1 | c.4782G>A p.K1594= | Splice Region (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100993885; called by muse, mutect2, varscan2
- COL4A2 | c.2018G>A p.R673K | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV100847455; called by muse, mutect2
- COL6A1 | c.1119+1G>A p.X373_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100720411; called by muse, mutect2
- CORO1B | c.440T>G p.V147G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100396721; called by muse, mutect2, varscan2
- CREB3L1 | c.664C>G p.P222A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV99915242; called by muse, varscan2
- CSMD3 | c.5294G>C p.R1765P (on ENST00000297405 / NM_001363185.1; = p.R1661P on NM_052900.3) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); catalogued as COSV52165347, COSV99844662; called by muse, mutect2, varscan2
- CTDP1 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs751142100, COSV99311029; called by muse, mutect2
- CYP4F3 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99658591; called by muse, mutect2
- DAZAP2 | c.392G>C p.G131A | Missense Mutation (SNP) | VAF 25/489 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV101199439; called by muse, mutect2
- DCST2 | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as COSV99792183; called by muse, mutect2
- DIP2C | c.4596G>C p.E1532D | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55175453, COSV99793385; called by muse, mutect2, varscan2
- DISC1 | c.998G>T p.W333L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as COSV99698442; called by muse, mutect2, varscan2
- DNMT1 | c.1812C>G p.I604M | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100532939; called by muse, mutect2
- DNTTIP2 | c.2042G>A p.R681K | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100785206; called by muse, mutect2
- DNTTIP2 | c.1944G>C p.M648I | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100785207; called by muse, mutect2
- DUSP22 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100740023; called by muse, mutect2, varscan2
- DYSF | c.2690C>A p.T897K | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.82); catalogued as COSV99249939; called by muse, mutect2
- EEF1A2 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV99419772; called by muse, mutect2, varscan2
- EFCAB5 | c.2921G>T p.R974M | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100300618; called by muse, mutect2, varscan2
- EFHD1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs755428001, COSV99898610; called by muse, mutect2, varscan2
- EIF2B2 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99837752, COSV99837764; called by muse, mutect2
- EIF2B2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.304); catalogued as COSV99837765; called by muse, mutect2
- ELK4 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV99222259; called by muse, mutect2, varscan2
- ELK4 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99222497; called by muse, mutect2, varscan2
- EPHA3 | c.2749G>T p.G917C | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100347954; called by muse, mutect2, varscan2
- EXOC6 | c.2338C>T p.R780* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as rs760629495, COSV53319461; called by muse, mutect2, varscan2
- FAM47C | c.2287C>A p.R763S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV100792912, COSV63723682; called by muse, mutect2, varscan2
- FGF13 | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as COSV100264541; called by muse, mutect2
- FHDC1 | c.2150T>A p.L717H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.299); catalogued as COSV99471623; called by muse, mutect2, varscan2
- FKBPL | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as COSV100913600; called by muse, mutect2, varscan2
- FMR1NB | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.051); catalogued as COSV100975602, COSV65072962; called by muse, mutect2
- FOSB | c.127-1G>A p.X43_splice | Splice Site (SNP) | VAF 28/146 reads (19%) | catalogued as COSV100798809; called by muse, mutect2, varscan2
- FOXM1 | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as COSV100700897; called by muse, mutect2
- FRMD4A | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV99198637; called by muse, mutect2, varscan2
- FRMPD2 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV100564105; called by muse, mutect2
- FSTL5 | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV100059962, COSV60198351; called by muse, mutect2, varscan2
- GBA3 | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV101545552; called by muse, mutect2
- GCNA | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 44/402 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs377418953, COSV101032652; called by muse, varscan2
- GDI1 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50131016, COSV99341176; called by muse, mutect2, varscan2
- GPC4 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100895586; called by muse, mutect2
- GPR85 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV99775269; called by muse, mutect2, varscan2
- GPRASP1 | c.1765C>A p.Q589K | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1410220542, COSV100851063; called by muse, mutect2
- GRIN2B | c.4369C>T p.P1457S | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1317229312, COSV101663157; called by muse, mutect2
- GTPBP10 | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1375473066, COSV99746143; called by muse, mutect2, varscan2
- H2BC10 | c.69G>C p.Q23H | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1561767959, COSV100010274, COSV59952887; called by muse, mutect2
- H2BW1 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.209); catalogued as COSV54220215, COSV99475140; called by muse, mutect2, varscan2
- HNRNPU | c.662C>G p.S221* (on ENST00000283179; = p.S283* on NM_004501.3) | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99310608; called by muse, mutect2
- HOXA1 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99761381; called by muse, mutect2
- HPRT1 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100053289; called by muse, mutect2, varscan2
- HRC | c.854C>A p.S285* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV99418251; called by muse, mutect2, varscan2
- HSPA4 | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100507826; called by muse, mutect2, varscan2
- IDH1 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1428437794, COSV61637645; called by muse, mutect2, varscan2
- IFIH1 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99718821; called by muse, mutect2
- IGDCC4 | c.1960C>T p.H654Y | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV100733106; called by muse, mutect2
- IGF1R | c.2041G>C p.E681Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV99159597; called by muse, mutect2
- IGKV1D-17 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1396712608; called by muse, mutect2
- IGSF9B | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100318186, COSV100318259; called by muse, mutect2
- IKZF3 | c.103C>G p.H35D | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV99500096; called by muse, mutect2
- IL22 | c.86A>T p.Q29L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100048935; called by muse, mutect2, varscan2
- IL4I1 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV100352293; called by muse, mutect2
- KCNQ3 | c.2456G>T p.G819V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as COSV66469244; called by muse, mutect2, varscan2
- KIAA1522 | c.557C>A p.P186H (on ENST00000373480 / NM_001198972.2; = p.P245H on NM_020888.3) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); catalogued as COSV99615015; called by muse, mutect2
- KIR3DL3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1277875430, COSV52550084; called by muse, mutect2
- L3HYPDH | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV99711724; called by muse, mutect2, varscan2
- L3HYPDH | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV99711726; called by muse, mutect2, varscan2
- L3MBTL1 | c.1526C>T p.P509L (on ENST00000418998 / NM_001377303.1; = p.P419L on NM_015478.7) | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV100917044; called by muse, mutect2, varscan2
- LARGE1 | c.1627G>T p.V543L | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100506186, COSV61662816; called by muse, mutect2
- LBH | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101257811; called by muse, mutect2, varscan2
- LRFN5 | c.1579G>T p.G527C | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985099; called by muse, mutect2
- LRP1 | c.11617G>T p.A3873S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV99676907; called by muse, mutect2
- LRP2 | c.12559C>A p.P4187T | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99789874; called by muse, mutect2
- LSAMP | c.919A>T p.R307* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100372438; called by muse, mutect2, varscan2
- MAGEA3 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 36/208 reads (17%) | catalogued as COSV100939080; called by muse, varscan2
- MAGEE1 | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100819502; called by muse, mutect2
- MAML1 | c.637A>T p.N213Y | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV99483323; called by muse, mutect2
- MC1R | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100206028; called by muse, mutect2, varscan2
- MCC | c.1112G>C p.C371S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.175); catalogued as COSV100203132; called by muse, mutect2, varscan2
- METTL25 | c.78C>A p.F26L | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99810782; called by muse, mutect2
- MIER2 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV99316662; called by muse, mutect2, varscan2
- MNS1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as COSV99549781; called by muse, mutect2
- MROH9 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.339); catalogued as COSV100882973, COSV100883129; called by muse, mutect2, varscan2
- MTA2 | c.1158G>C p.M386I | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99545541; called by mutect2, varscan2
- MYH1 | c.3370G>T p.E1124* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99876677; called by muse, mutect2, varscan2
- NAALADL2 | c.1436C>G p.S479* | Nonsense Mutation (SNP) | VAF 24/133 reads (18%) | catalogued as COSV101380447; called by muse, mutect2, varscan2
- NCF4 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.365); catalogued as COSV50625284; called by muse, mutect2
- NCKAP1L | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99515560; called by muse, mutect2
- NDUFB5 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99372646; called by muse, mutect2, varscan2
- NEB | c.7651T>C p.Y2551H | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99426833; called by muse, mutect2, varscan2
- NELL2 | c.717G>C p.Q239H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); catalogued as COSV100420491; called by muse, mutect2
- NF1 | c.3315-1G>T p.X1105_splice | Splice Site (SNP) | VAF 14/40 reads (35%) | catalogued as CS1311523, COSV100648035, COSV62205938; called by muse, mutect2, varscan2
- NFATC3 | c.2533G>T p.G845C | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV100285624; called by muse, mutect2, varscan2
- NFE2L2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67960064; called by muse, mutect2
- NID1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99936959; called by muse, mutect2, varscan2
- NIPBL | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV99242230; called by muse, mutect2, varscan2
- NLGN1 | c.1586C>A p.S529Y | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100849925; called by muse, mutect2
- NLRP13 | c.2641G>T p.A881S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.029); catalogued as rs1253950687, COSV100738441; called by muse, mutect2
- NPR3 | c.381G>T p.K127N | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99423720; called by muse, mutect2
- NRCAM | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61030439, COSV61035172; called by muse, mutect2
- NT5C3A | c.637G>T p.G213C (on ENST00000610140 / NM_001374335.1; = p.G179C on NM_016489.13) | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771902706, COSV54237555, COSV99641377; called by muse, mutect2, varscan2
- OCA2 | c.1596G>T p.W532C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV100668502; called by muse, mutect2
- OR13H1 | c.239A>T p.Q80L | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV100088374; called by muse, mutect2
- OR2D2 | c.925T>A p.*309Rext*7 | Nonstop Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as COSV100203909; called by muse, mutect2
- OR2T27 | c.343C>A p.L115I | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100788358; called by muse, mutect2, varscan2
- OR4Q3 | c.109T>A p.L37I | Missense Mutation (SNP) | VAF 23/276 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.318); catalogued as COSV100057297; called by muse, mutect2
- PARP4 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV101131973; called by muse, mutect2
- PCDH1 | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 5/90 reads (6%) | catalogued as COSV99746812; called by muse, mutect2
- PCDH10 | c.1083C>G p.S361R | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99994313; called by muse, mutect2
- PCDHA12 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100253553; called by muse, mutect2, varscan2
- PCDHA6 | c.1818G>T p.W606C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100971260, COSV100971730; called by muse, mutect2, varscan2
- PHKA1 | c.2036C>A p.P679H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100263790; called by muse, mutect2, varscan2
- PIR | c.566-1G>T p.X189_splice | Splice Site (SNP) | VAF 13/186 reads (7%) | catalogued as COSV100990699; called by muse, mutect2
- PLCB3 | c.2717C>G p.S906* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99657676; called by muse, mutect2
- PLCB4 | c.2711G>T p.G904V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99596671; called by muse, mutect2
- PLCE1 | c.3207G>T p.E1069D | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV99596728; called by muse, mutect2
- PLEKHG4B | c.3533C>T p.S1178F (on ENST00000283426; = p.S1534F on NM_052909.5) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99360921; called by muse, mutect2, varscan2
- PLOD3 | c.1910G>T p.S637I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs755547790, COSV99778235; called by muse, mutect2, varscan2
- PLOD3 | c.1909A>G p.S637G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99778236; called by muse, mutect2, varscan2
- PLXNA3 | c.970G>C p.G324R | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859822, COSV100860202; called by muse, mutect2
- PMS2 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1278184308, COSV99764495; called by muse, mutect2, varscan2
- PNPLA2 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.555); catalogued as COSV100352132; called by muse, mutect2
- POC1B | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100544445; called by muse, mutect2
- POSTN | c.2173C>A p.H725N | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.351); catalogued as COSV101123463; called by muse, mutect2
- POU4F3 | c.222C>A p.F74L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100047231; called by muse, mutect2
- PPP2R2C | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/89 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs747864353, COSV100067146; called by muse, mutect2, varscan2
- PRDM9 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99691041; called by muse, mutect2
- PTPN12 | c.2099G>C p.S700T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV99950637; called by muse, varscan2
- RAB38 | c.610A>G p.S204G | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs748892433, COSV99703330; called by muse, mutect2, varscan2
- RACK1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.419); catalogued as COSV100958809; called by muse, mutect2, varscan2
- RANBP2 | c.1406C>G p.S469* | Nonsense Mutation (SNP) | VAF 10/208 reads (5%) | catalogued as COSV51699399, COSV99313020; called by muse, mutect2
- RECQL | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 11/117 reads (9%) | catalogued as COSV100131344; called by muse, mutect2
- RGS22 | c.3334G>A p.G1112R | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753311396, COSV100693693; called by muse, mutect2
- RXFP1 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100314127; called by muse, mutect2
- SCN10A | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV71862232; called by muse, mutect2
- SEMA6D | c.2041G>T p.V681L (on ENST00000316364 / NM_153618.2; = p.V619L on NM_020858.2) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV100317453; called by muse, mutect2, varscan2
- SETD2 | c.3932G>A p.G1311D | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV57442438; called by muse, mutect2
- SIMC1 | c.1537A>T p.I513F (on ENST00000443967 / NM_001308196.1; = p.I98F on NM_198567.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV100365873; called by muse, mutect2, varscan2
- SLC12A3 | c.2118G>T p.K706N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV99344624; called by muse, mutect2, varscan2
- SLC13A2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs144449087; called by muse, mutect2, varscan2
- SLC22A12 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100327837; called by muse, mutect2
- SLC24A2 | c.1718T>C p.I573T | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99647279; called by muse, mutect2
- SLC35F2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99758830; called by muse, mutect2
- SLC5A11 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1567658010, COSV61744060; called by muse, mutect2, varscan2
- SLC8A2 | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV99370265; called by muse, mutect2
- SLC9B2 | c.1256-1G>A p.X419_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | catalogued as rs1300199647, COSV100294256; called by muse, mutect2
- SMPD2 | c.84C>A p.D28E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99238125; called by muse, mutect2, varscan2
- SNAP91 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.076); catalogued as COSV99534938, COSV99536322; called by muse, mutect2, varscan2
- SNX32 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100362645, COSV100362673; called by muse, mutect2, varscan2
- SORCS3 | c.2670G>T p.Q890H | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100863751, COSV63798820; called by muse, mutect2, varscan2
- SPAG17 | c.2800G>C p.E934Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100310208; called by muse, mutect2
- SPAG5 | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100410807; called by muse, mutect2
- SPATA6L | c.384G>T p.R128S (on ENST00000461761 / NM_001353484.2; = p.R70S on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99795093; called by muse, mutect2
- SPATA7 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as COSV99248289; called by muse, mutect2, varscan2
- SRRM2 | c.2078G>T p.R693L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.045); catalogued as COSV100071340, COSV57073625; called by muse, mutect2, varscan2
- SRSF6 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV99719818; called by muse, mutect2
- SSH1 | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV100425499, COSV100425791; called by muse, mutect2, varscan2
- SSX7 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV53339772; called by muse, mutect2
- STEAP4 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV100112693; called by muse, mutect2
- SUN1 | c.1000A>G p.I334V (on ENST00000405266 / NM_001367651.1; = p.I214V on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100568780; called by muse, mutect2
- SV2C | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1290610267, COSV100456689; called by muse, mutect2
- SVEP1 | c.4675A>C p.K1559Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV100990894, COSV65682182; called by muse, mutect2
- TAAR5 | c.291G>C p.E97D | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV99236979; called by muse, mutect2
- TAF1 | c.1177G>A p.D393N (on ENST00000373790 / NM_138923.4; = p.D414N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV99336654, COSV99336764; called by muse, mutect2
- TAF9 | c.132C>G p.F44L | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV54204503, COSV99472816; called by muse, mutect2
- TAS2R30 | c.361A>T p.I121L | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201847619; called by muse, mutect2, varscan2
- TBC1D10A | c.1476C>A p.H492Q | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.806); catalogued as COSV99304906; called by muse, mutect2, varscan2
- TELO2 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs758349535, COSV99248640; called by muse, varscan2
- TENM1 | c.5371G>T p.A1791S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100950652; called by muse, mutect2, varscan2
- TENM1 | c.218-1G>A p.X73_splice | Splice Site (SNP) | VAF 17/145 reads (12%) | catalogued as COSV100950410, COSV100950653; called by muse, mutect2
- TEX15 | c.5953G>A p.D1985N (on ENST00000256246; = p.D2368N on NM_001350162.2) | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV99821963; called by muse, mutect2
- THOC6 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV50188459, COSV99560830; called by mutect2, varscan2
- TIGD3 | c.662G>T p.R221I | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.229); catalogued as COSV99361889; called by muse, mutect2
- TLR10 | c.230T>A p.L77* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100457974; called by muse, mutect2, varscan2
- TLR10 | c.229T>A p.L77M | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100457977; called by muse, mutect2, varscan2
- TMEM161A | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV99365558; called by muse, mutect2, varscan2
- TMEM38B | c.625A>G p.M209V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV101016555; called by muse, mutect2
- TMEM95 | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99341916; called by mutect2, varscan2
- TOX | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100813065; called by muse, mutect2, varscan2
- TPSG1 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV99327028; called by muse, mutect2
- TRIM24 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100631188, COSV58977420; called by muse, mutect2, varscan2
- TRIM42 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99648735; called by muse, mutect2
- TRO | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV99437141; called by muse, mutect2
- TRPM8 | c.2900C>A p.T967N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100224443, COSV61221113; called by muse, mutect2
- TTC12 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.402); catalogued as rs895550287, COSV100133293; called by muse, mutect2, varscan2
- TTC7A | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | catalogued as COSV99766871; called by muse, mutect2
- TUBGCP3 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99997136; called by muse, mutect2, varscan2
- UBE4A | c.2944G>T p.E982* (on ENST00000252108 / NM_001204077.2; = p.E989* on NM_004788.4) | Nonsense Mutation (SNP) | VAF 22/124 reads (18%) | catalogued as COSV99348519; called by muse, mutect2, varscan2
- UGT1A1 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100530810; called by muse, mutect2
- UPP2 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99135165; called by muse, mutect2, varscan2
- USH2A | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as CM135886, COSV100240811; called by muse, mutect2, varscan2
- USP29 | c.4A>T p.I2L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99572408; called by muse, mutect2, varscan2
- UTP14A | c.2041C>T p.Q681* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV100929000; called by muse, mutect2
- UTS2B | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 23/133 reads (17%) | catalogued as COSV100484337; called by muse, mutect2, varscan2
- VPS13D | c.2491G>A p.V831M | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.96); catalogued as COSV99168294; called by muse, mutect2, varscan2
- VSIG1 | c.496G>T p.G166* | Nonsense Mutation (SNP) | VAF 17/177 reads (10%) | catalogued as COSV99480439; called by muse, mutect2
- WASL | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.996); catalogued as COSV99771812; called by muse, mutect2, varscan2
- WRN | c.4078G>C p.D1360H | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99988249, COSV99989700; called by muse, mutect2
- WSCD1 | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV100496420, COSV100496764; called by muse, mutect2
- XYLB | c.888G>T p.A296= | Splice Region (SNP) | VAF 9/57 reads (16%) | catalogued as COSV52913966; called by muse, mutect2, varscan2
- YAE1 | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99785026; called by muse, mutect2, varscan2
- ZNF213 | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV101206044; called by muse, mutect2, varscan2
- ZNF439 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV100397544, COSV58309449; called by muse, mutect2
- ZNF653 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs1344912460, COSV53402334, COSV99542308; called by muse, mutect2, varscan2
- ZNF676 | c.485G>C p.R162T (on ENST00000650058; = p.R130T on NM_001001411.3) | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV101236309, COSV68095125; called by muse, mutect2, varscan2
- ZNF91 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1233047856, COSV100323361; called by muse, mutect2
- ZSCAN22 | c.691A>G p.S231G | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV100308472; called by muse, mutect2
- ZSWIM2 | c.375C>A p.D125E | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99720453; called by muse, mutect2, varscan2
- C5AR1 | c.813_815del p.S272del | In Frame Del (DEL) | VAF 11/104 reads (11%) | called by mutect2, pindel
- DCAF8 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- ELMOD2 | c.736_736+12del p.X246_splice | Splice Site (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- ENC1 | c.1697del p.N566Tfs*10 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- FAM135A | c.2776dup p.S926Ffs*3 (on ENST00000370479 / NM_001351599.1; = p.S713Ffs*3 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 6/68 reads (9%) | called by mutect2, pindel
- IGHA1 | c.858C>G p.S286R | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2
- MRC1 | c.3947C>G p.S1316C | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- NOTCH3 | c.3291del p.T1098Pfs*174 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel
- RIMS2 | c.2557C>T p.Q853* (on ENST00000666250 / NM_001348490.2; = p.Q661* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- ABCA6 | c.4389G>A p.E1463= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs758022121, COSV99447464; called by muse, mutect2, varscan2
- ACSS2 | c.273C>A p.I91= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV99490113; called by muse, mutect2
- ADGRE1 | c.2421G>T p.L807= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- ALAS2 | c.933G>A p.K311= | Silent (SNP) | VAF 11/150 reads (7%) | catalogued as rs746627894, COSV100238556, COSV58189379; called by muse, mutect2
- ALOXE3 | c.517T>C p.L173= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as COSV100559909; called by muse, mutect2
- BTN3A3 | c.1173A>C p.T391= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV99765025; called by muse, mutect2
- CACNA1C | c.6570G>A p.A2190= (on ENST00000399634 / NM_001167625.1; = p.A2119= on NM_000719.7) | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs915771697, COSV100221645; called by muse, mutect2
- CLIP1 | c.285C>T p.P95= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as rs749881060, COSV100212247; called by muse, mutect2
- CNGA4 | c.54C>G p.S18= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99792438; called by muse, mutect2
- CUX2 | c.3243C>A p.S1081= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99920523; called by muse, mutect2, varscan2
- CXorf56 | c.312A>G p.A104= (on ENST00000536133 / NM_001170570.2; = p.A118= on NM_022101.4) | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as COSV100233454; called by muse, mutect2
- CYFIP2 | c.1413C>T p.F471= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs1328397891, COSV100557645; called by muse, mutect2
- DCLK3 | c.1176C>G p.L392= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV101374076; called by muse, mutect2, varscan2
- DUSP10 | c.864C>T p.L288= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as COSV100100738; called by muse, mutect2
- EEFSEC | c.729G>T p.G243= | Silent (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- ELK4 | c.519G>A p.E173= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99222495; called by muse, mutect2, varscan2
- EXD2 | c.492T>A p.V164= (on ENST00000312994 / NM_001193362.1; = p.V39= on NM_018199.3) | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as COSV100474272, COSV100474418; called by muse, mutect2, varscan2
- FANCM | c.2959C>T p.L987= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV99951525; called by muse, mutect2, varscan2
- FOXK1 | c.1278G>A p.L426= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV100195691; called by muse, mutect2
- GABRA1 | c.52C>T p.L18= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV50102574, COSV99196207; called by muse, mutect2
- GPATCH2 | c.424C>T p.L142= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV100861406, COSV65128886; called by muse, mutect2
- GPR132 | c.483C>T p.L161= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100317708; called by muse, mutect2
- GRIA4 | c.165C>T p.P55= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV56898900, COSV99233892; called by muse, mutect2, varscan2
- H1-5 | c.168G>A p.E56= | Silent (SNP) | VAF 11/151 reads (7%) | catalogued as rs1423795272, COSV100138042, COSV58901094; called by muse, mutect2
- HSPA4 | c.2256G>A p.Q752= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100507827; called by muse, mutect2
- JADE1 | c.159C>T p.I53= | Silent (SNP) | VAF 15/203 reads (7%) | catalogued as COSV99886176; called by muse, mutect2
- KIAA0100 | c.3045C>T p.L1015= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV101197388; called by muse, mutect2, varscan2
- KIAA0232 | c.1395C>T p.F465= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV100301038; called by muse, mutect2
- KIAA1217 | c.705C>T p.Y235= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs1309255311, COSV100908293; called by muse, mutect2, varscan2
- KMT2A | c.4365C>T p.F1455= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as rs1565291793, COSV100629646; called by muse, mutect2
- LZTS2 | c.960G>T p.S320= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV100932263; called by muse, mutect2, varscan2
- NAA25 | c.243A>T p.S81= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV99927953; called by muse, mutect2
- NKAIN2 | c.396C>A p.R132= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100863838; called by muse, mutect2, varscan2
- NUCB1 | c.1041G>A p.L347= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV54387814; called by muse, mutect2
- NUTM2F | c.1158C>A p.V386= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV53559946, COSV99480374; called by muse, mutect2, varscan2
- OLFM2 | c.342C>T p.L114= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99321976, COSV99322050; called by muse, mutect2, varscan2
- OR10C1 | c.141G>A p.V47= (on ENST00000622521; = p.V45= on NM_013941.3) | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV101010885; called by muse, varscan2
- OR10K1 | c.534C>T p.F178= | Silent (SNP) | VAF 75/314 reads (24%) | catalogued as COSV99193878; called by muse, mutect2, varscan2
- OR10K1 | c.666C>A p.I222= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV56873848, COSV99193881; called by muse, mutect2, varscan2
- OR2V2 | c.627C>G p.L209= | Silent (SNP) | VAF 16/211 reads (8%) | catalogued as COSV100080220; called by muse, mutect2
- P2RY10 | c.408C>G p.L136= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV99409318; called by muse, mutect2, varscan2
- PCDH9 | c.213G>T p.G71= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100122833, COSV100123878; called by muse, mutect2
- PCDHGA3 | c.1407C>A p.A469= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as COSV99545099; called by muse, mutect2
- PDGFC | c.1023G>A p.G341= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs373720182; called by muse, mutect2, varscan2
- PDHA2 | c.9C>A p.A3= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV54778770, COSV54781115, COSV99757229; called by muse, varscan2
- PGBD2 | c.1329G>C p.T443= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100252197; called by muse, mutect2, varscan2
- PIK3CA | c.1641G>A p.E547= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV55888836, COSV55939262; called by muse, mutect2
- PIKFYVE | c.561C>T p.F187= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as COSV100011305; called by muse, mutect2, varscan2
- PIWIL4 | c.582G>A p.E194= | Silent (SNP) | VAF 13/186 reads (7%) | catalogued as COSV100133379; called by muse, mutect2
- PRDM16 | c.1683C>T p.A561= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs771966209, COSV54605375; called by muse, mutect2, varscan2
- RAD51AP2 | c.84C>T p.S28= | Silent (SNP) | VAF 8/139 reads (6%) | catalogued as COSV101208402, COSV67589414; called by muse, mutect2
- RNF133 | c.876A>T p.T292= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as COSV100411721; called by mutect2, varscan2
- RYR2 | c.10593C>T p.Y3531= | Silent (SNP) | VAF 9/189 reads (5%) | catalogued as COSV100772281; called by muse, mutect2
- SAT1 | c.474G>A p.K158= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100803906; called by muse, mutect2, varscan2
- SESN2 | c.1263C>T p.L421= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV99456061; called by muse, mutect2
- SLC17A4 | c.9C>A p.T3= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100930490; called by mutect2, varscan2
- SLC7A7 | c.1284C>T p.T428= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99591284; called by muse, mutect2
- SLC9A6 | c.1215G>A p.Q405= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV100857941; called by muse, mutect2
- SLCO2B1 | c.2007T>A p.V669= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV99215078; called by muse, mutect2, varscan2
- SORBS2 | c.2283C>T p.I761= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as COSV99512374; called by muse, mutect2
- STEAP1 | c.945G>A p.K315= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV99787760; called by muse, mutect2
- TAGAP | c.300C>A p.L100= | Silent (SNP) | VAF 14/206 reads (7%) | catalogued as COSV100487615; called by muse, mutect2
- URB2 | c.3213C>T p.L1071= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV99271755; called by muse, mutect2, varscan2
- WDFY3 | c.3993G>T p.V1331= | Silent (SNP) | VAF 5/111 reads (5%) | catalogued as rs1284147265, COSV99885174; called by muse, mutect2
- XAGE3 | c.273G>A p.K91= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as COSV100655695; called by muse, mutect2
- ZNF254 | c.930T>G p.T310= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100741749; called by muse, mutect2
- ZNF385D | c.91C>T p.L31= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV99876020; called by muse, mutect2, varscan2
- ZNF609 | c.2124C>A p.P708= | Silent (SNP) | VAF 15/201 reads (7%) | catalogued as COSV100441668; called by muse, mutect2
- AC073310.1 | n.569G>T | RNA (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- ADARB2 | c.101-177626C>A | Intron (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- AL136982.4 | n.348G>T | RNA (SNP) | VAF 40/260 reads (15%) | called by muse, mutect2, varscan2
- DCAF13 | c.-28G>T | 5'UTR (SNP) | VAF 12/76 reads (16%) | catalogued as rs773486449, COSV99884632; called by muse, mutect2, varscan2
- NBPF11 | c.-549+2426C>T | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- POLA1 | c.2947-21310C>T | Intron (SNP) | VAF 20/240 reads (8%) | catalogued as rs371802121; called by muse, mutect2
- SSPOP | n.13371C>T | RNA (SNP) | VAF 17/86 reads (20%) | catalogued as rs977955663, COSV100947920; called by muse, mutect2, varscan2
